Surgical pathology report (de-identified scan), TCGA case TCGA-VD-AA8T, project TCGA-UVM (Uveal Melanoma), tissue source site University of Liverpool, specimen TCGA-VD-AA8T-01A (Primary Tumor).

[page 1 of 3]
Department of Pathology					
, HISTOPATHOLOGY					
Surname	Lab No		Clinical Consultant & Location		
Forename(s)	DOB/Age	Sex			
Unit No	Request Date				

This Copy For:

SPECIMEN

LEFT GLOBE ENUCLEATION (FOR DIAGNOSTIC AND PROGNOSTIC)

CLINICAL DETAILS

See diagram. Measurements 14.28 x 14.26 x (9.49)mm.

MACROSCOPIC DESCRIPTION

A fresh, intact left globe.

Dimensions: Axial 24.5mm, Horizontal 24mm, Vertical 24mm

Cornea: Horizontal 11.5mm, Vertical 10.8mm

Description: arcus senilis.

Optic nerve

Length 7mm, diameter 4mm

Pupil: very dilated

On trans-illumination, a large shadow is seen on the medium side. Approx 18mm.

Plane of section: horizontal

Intraocular description:

On opening, a solitary pigmented dome shaped choroidal mass is seen. There is probable ciliary body involvement. Posterior edge is 11mm from optic disc.

Tumour size

LBD 12mm, Height 9mm

MICROSCOPY

Sections show a partially pigmented ciliochoroidal melanoma consisting predominantly of spindle cells. The number of mitosis is approximately 2/40 high power fields. Closed loops are present in the planes of sections. The lymphocytic infiltrate within the tumour is minimal. Scattered macrophages are present. Tumour necrosis is not seen. Bruch's membrane appears breached in the sections examined.

*ICD-O 3
Melanoma, spindle cell NOS 8772/3
Site: Overlapping lesion of eye & adnexa
0698
7/05/30/14*

Reported:

Pathologist:

Electronically Verified:

[page 2 of 3]
Department of Pathology			Page 2 of 3
HISTOPATHOLOGY REPORT Tel:			
Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For:

There is no tumour extension through the sclera, optic nerve or vortex veins examined. Tumour extends very close to anterior chamber angle and trabecular meshwork however no definitive evidence of ring pattern of spread is seen. Tumour cells are not seen at the resection margins.

Elsewhere, the cornea shows no significant abnormality apart from oedema in basal epithelial cells. The anterior chamber angles are open and the anterior chamber is deep. The iris shows no significant abnormality but the ciliary body away from the tumour appears atrophic with hyalinisation of ciliary processes. Lens remnants show cataractuous changes. Retina overlying the tumour is slightly atrophic.

DIAGNOSIS

Left eye, enucleation: Ciliochoroidal melanoma of predominantly spindle cell type.

COMMENT

Assessment of Melan-A and HSP 27 expression will be carried out. In addition, molecular genetic examination of DNA extracted from the tumour cells will be performed using multiplex-ligation dependent probe amplification (MLPA), looking at chromosomes 1, 3, 6 and 8. A supplementary report will follow in due course.

SUPPLEMENTARY REPORT

In the meantime, immunohistochemical stains were performed. The tumour cells stain for MelanA and partially for HSP-27 (score 1).

SUPPLEMENTARY REPORT (MLPA)

In the meantime, molecular genetic analysis of tumour DNA extracted from the fresh uveal melanoma tissue was performed using the technique termed multiplex ligation-dependent probe amplification (MLPA). These investigations were performed in the

The kit P027 from [REDACTED], which examines for gains or

Reported:

Pathologist: [REDACTED]

Electronically Verified: [REDACTED]

[page 3 of 3]
Department of Pathology

Page 3 of 3

, HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED] [REDACTED]
Forename(s) [REDACTED]	DOB/Age [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]	

This Copy For: [REDACTED]

losses in 31 loci on chromosomes 1, 3, 6 and 8, was used. The DNA concentration was measured using [REDACTED] and the quality assessed using multiplex-PCR prior to the MLPA reaction.

The DNA concentration was high and of good quality on assessment. The MLPA reaction was run at least twice on differing occasions, resulting in similar results.

The results of the sequence analysis of the MLPA products is printed on a separate report. In summary, sequence analysis demonstrated:

Loss of chromosome 1p,
monosomy 3,
normal chromosome 6
and gains in chromosome 8.

These molecular data require correlation with the clinical and morphological data for metastatic risk assessment.

Reported:

Pathologist: [REDACTED]
Electronically Verified: [REDACTED]

Source: NCI Genomic Data Commons file 40332128-26e6-420f-9810-83363bbcfb88 (TCGA-VD-AA8T.FFC65F78-4178-4E52-B5AF-1808C61EAED0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).